Somatic mutation profile of tumor specimen TCGA-2G-AAFG-05A (aliquot TCGA-2G-AAFG-05A-11D-A42Y-10) from TCGA case TCGA-2G-AAFG, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 30.1 years (11,002 days).
Specimen TCGA-2G-AAFG-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a40663fa-ed8a-4d88-a2a8-1567aa767cba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFG-10A (Blood Derived Normal), aliquot TCGA-2G-AAFG-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e57c578d-28be-483c-b7d2-4e6c209e78f4

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2B | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs957188913, COSV100754180; called by muse, mutect2, varscan2
- CUL4A | c.1312A>T p.I438F (on ENST00000375440 / NM_001008895.4; = p.I338F on NM_003589.3) | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1300087654; called by muse, mutect2
- ITPR3 | c.5092C>G p.R1698G | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs774177342, COSV104428103; called by muse, mutect2, varscan2
- NAP1L3 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59077323; called by muse, mutect2, varscan2
- ARID4B | c.3227G>C p.G1076A | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HLX | c.693C>G p.N231K | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LUC7L3 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED12L | c.3875G>A p.C1292Y | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SAFB | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TET1 | c.4415C>G p.T1472S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTF1 | c.1589A>G p.Q530R | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- UBR5 | c.7551G>T p.R2517S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ZNF782 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- B3GALT4 | c.408G>T p.G136= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.348C>A | RNA (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
